Surgical pathology report (de-identified scan), TCGA case TCGA-60-2710, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2710-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. APICAL POSTERIOR SEGMENT LEFT LUNG BX
B. LEVEL 5 LYMPH NODE
C. LEVEL 6 LYMPH NODE
D. LEVEL 7 LYMPH NODE
E. LEVEL 9 LYMPH NODE
F. LEFT UPPER LOBE

CLINICAL HISTORY:

PRE-OPERATIVE DIAGNOSIS:

Left apical lung mass

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSB, FSC, FSD, FSE: Lymph nodes, levels 5, 6, 7, 9, biopsies: Negative for carcinoma, See comment.

Comment: Half of each node submitted for protocol after touch preparations. Receiving half frozen.

FSF: Lung, left upper lobe, lobectomy: Bronchial margin negative for carcinoma.

GROSS DESCRIPTION:

A. APICAL POSTERIOR SEGMENT LEFT LUNG BIOPSY

Received in formalin is a tiny pink-tan segment of soft tissue obtained after filtration through the biopsy bag, measuring 0.3x0.2x0.1cm. The entire tissue is submitted with the biopsy bag in a single cassette A1.

B. LEVEL 5 LYMPH NODE

[page 2 of 3]
Received fresh and consists of multiple tan-black lymph nodes, measuring 1.8x1.1cm in aggregate. The specimen is bisected. Touch preps are made. Half of the specimen is sent for procurement and the remaining specimen is frozen for intraoperative diagnosis.

C. LEVEL 6 LYMPH NODE

Received fresh and consists of small tan-black lymph nodes, measuring 1.2x1.0cm. The specimen is bisected. Touch preps are made. Half of the specimen is submitted for procurement and remaining half is frozen for intraoperative diagnosis.

D. LEVEL 7 LYMPH NODE

Received fresh and consists of tan-black lymph nodes, measuring 1.1x1.0cm. Specimen is bisected and touch preps are made. Half of the specimen is sent for procurement and rest of the specimen is submitted for frozen section for intraoperative diagnosis.

E. LEVEL 9 LYMPH NODE

Received fresh and consists of multiple black lymph nodes, measuring 0.7x0.5cm. Touch preps are made. Half of the specimen is submitted for procurement and rest of the specimen is submitted for frozen section for intraoperative diagnosis.

F. LEFT UPPER LOBE

Received fresh and subsequently fixed is a left upper lobe weighing 172gm, measuring (15x11x2cm). An ill-defined, gray-tan, firm, sub pleural nodular lesion is identified in the peripheral region measuring 2.0x1.7x1.5cm which is 4.0cm from the bronchial margin and 2.0 cm from the pleural surface. The overlying tumor surface is slightly retracted and puckered. A firm, anthracotic (1.0x0.8x0.6cm) lymph node is identified near the bronchial margin. Rest of the lung parenchyma is sectioned to reveal moderate emphysematous changes. Representative sections are submitted as follows:

F1 – F2: bronchial margin.

F3: sections from the lymph node.

F4-F6: nodular lesion in toto with adjacent pleural margin

F7: lung tissue adjacent to the nodule

F8: grossly unremarkable random section of lung tissue

DIAGNOSIS:

A. APICAL POSTERIOR SEGMENT, LEFT LUNG, BIOPSY:

- SMALL FRAGMENT OF FIBROUS TISSUE CONTAINING PORTION OF BRONCHIAL EPITHELIUM, NO MALIGNANCY IDENTIFIED

B. LEVEL 5 LYMPH NODE, EXCISION:

- ONE LYMPH NODE SHOWING ANTHRACOTIC PIGMENT, NO MALIGNANCY IDENTIFIED

C. LEVEL 6 LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR, PENDING CYTOKERATIN STAIN
-

[page 3 of 3]
D. LEVEL 7 LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NO TUMOR SEEN (0/1)

E. LEVEL 9 LYMPH NODE, EXCISION:

- ONE LYMPH NODE SHOWING ANTHRACOTIC PIGMENT, NO TUMOR SEEN (0/1)

F. LEFT UPPER LOBE, LOBECTOMY:

- SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, TUMOR SIZE 2 X 1.7 CM
- METASTATIC CARCINOMA PRESENT IN ONE PERIBRONCHIAL LYMPH NODE (1/1)
- PLEURAL SURFACE, NEGATIVE FOR TUMOR
- BRONCHIAL MARGIN, NEGATIVE FOR TUMOR
- SEE TEMPLATE

LUNG NEOPLASM TEMPLATE

Surgical procedure:	Lobectomy
Tumor location:	Peripheral LUL
Tumor size:	2.0 x 1.7 cm
Tumor type:	Squamous cell carcinoma
Histologic grade:	G2: Moderately differentiated
Angiolymphatic invasion:	Present based on the positive lymph node
Bronchial margin:	Negative
Visceral pleural involvement:	Absent
Satellite tumor(s):	No
Lymph node involvement:	N1: Ipsilateral Hilar (Level 10) and/or Peribronchial (Levels 11-14): Positive (1/1) N2: Ipsilateral Mediastinal (Levels 1-9) and/or subcarinal: Negative (0/4) N3: Contralateral mediastinal/hilar, Scalene or supraclavicular: NA
Non-neoplastic lung:	Unremarkable
Pathologic stage:	pT1 N1 MX

Source: NCI Genomic Data Commons file 6be1c49d-8a1f-4e2e-b731-11e0ba183edc (TCGA-60-2710.DA7DA3B9-53AF-4B12-BE95-07DFC7BE8458.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).